Somatic mutation profile of tumor specimen 0E03VA from CCDI case PBCUTF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E03VA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9b7dc46-4726-4337-8f4e-92e8ab56d9cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E03W6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51bd1dab-b912-47ba-8b6e-1c38dab7c49a

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 305/1178 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387906589, CM091421, COSV55115990, COSV55115998; ClinVar: likely pathogenic / other; called by muse, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 325/853 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, varscan2
- CFAP91 | c.1828C>T p.R610* | Nonsense Mutation (SNP) | VAF 259/715 reads (36%) | catalogued as rs747028037, COSV56341021; called by muse, varscan2
- COL19A1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 264/822 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753339843, COSV100505938, COSV59571242; called by muse, varscan2
- CSRNP1 | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 104/332 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56189958; called by muse, varscan2
- GFM2 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 246/742 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as rs956018389; called by muse, varscan2
- TLE2 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs577839395, COSV53582608; called by muse, varscan2
- ZC3H11B | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 230/622 reads (37%) | catalogued as rs1351208168, COSV65844879; called by muse, varscan2
- APC | c.4655_4656del p.E1552Gfs*6 | Frame Shift Del (DEL) | VAF 242/590 reads (41%) | called by pindel, varscan2
- AXIN2 | c.772_776dup p.S260Rfs*4 | Frame Shift Ins (INS) | VAF 179/718 reads (25%) | called by pindel, varscan2
- PRKAR1A | c.162dup p.E55* | Frame Shift Ins (INS) | VAF 180/936 reads (19%) | called by pindel, varscan2
- C4orf54 | c.2931G>A p.G977= | Silent (SNP) | VAF 142/384 reads (37%) | catalogued as rs1253362280; called by muse, varscan2
- DONSON | c.15G>A p.V5= | Silent (SNP) | VAF 80/202 reads (40%) | catalogued as rs531692338; called by muse, varscan2
- IGHMBP2 | c.1092G>T p.L364= | Silent (SNP) | VAF 146/414 reads (35%) | called by muse, varscan2
- MGAT1 | c.799C>T p.L267= | Silent (SNP) | VAF 132/329 reads (40%) | catalogued as rs973453570; called by muse, varscan2
- CPNE3 | c.820-45T>C | Intron (SNP) | VAF 108/558 reads (19%) | called by muse, varscan2
